Somatic mutation profile of tumor specimen TARGET-30-PAPZYZ-01A (aliquot TARGET-30-PAPZYZ-01A-01D) from TARGET case TARGET-30-PAPZYZ, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 1.5 years (550 days).
Specimen TARGET-30-PAPZYZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fbe237aa-0076-4e62-98f6-822ce4857938.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAPZYZ-10A (Blood Derived Normal), aliquot TARGET-30-PAPZYZ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a18e557-fa2b-4d38-9d62-c3f0b3f5f63d

The open-access MAF lists 23 somatic variants for this specimen: 20 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 17, Silent 3, Splice Site 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAMK2A | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV62248033; called by muse, mutect2, varscan2
- DNAH5 | c.937C>A p.L313M | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.378); catalogued as COSV54257026; called by muse, varscan2
- DTNA | c.846C>A p.N282K | Missense Mutation (SNP) | VAF 34/51 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52029242; called by muse, mutect2, varscan2
- FADS2 | c.1078-1G>T p.X360_splice | Splice Site (SNP) | VAF 16/42 reads (38%) | catalogued as COSV53903064; called by muse, mutect2, varscan2
- FXR2 | c.629C>G p.S210C | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV51521134; called by muse, mutect2, varscan2
- GAL3ST1 | c.928C>G p.H310D | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58893826; called by muse, mutect2, varscan2
- KBTBD7 | c.1333C>T p.P445S | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV65267277; called by muse, mutect2, varscan2
- KCTD8 | c.1100G>T p.S367I | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); catalogued as COSV63598363; called by muse, mutect2, varscan2
- KIF20B | c.-1-1G>T | Splice Site (SNP) | VAF 54/105 reads (51%) | catalogued as COSV53316738; called by muse, mutect2, varscan2
- MARK4 | c.700G>A p.G234R | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as rs1447493288, COSV53469463, COSV53469675; called by muse, mutect2, varscan2
- MLLT10 | c.1464G>T p.E488D | Missense Mutation (SNP) | VAF 53/93 reads (57%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.931); catalogued as COSV57005914; called by muse, mutect2, varscan2
- OCRL | c.2618C>A p.P873H | Missense Mutation (SNP) | VAF 74/349 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63982052; called by muse, mutect2, varscan2
- RSRC2 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.007); catalogued as rs747942191, COSV59204210; called by muse, mutect2, varscan2
- TACR1 | c.148A>C p.N50H | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59486776; called by muse, mutect2, varscan2
- TCEANC | c.7G>C p.D3H (on ENST00000380600 / NM_001297563.2; = p.D33H on NM_152634.4) | Missense Mutation (SNP) | VAF 96/222 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV59041102; called by muse, mutect2, varscan2
- TIAM2 | c.3931C>A p.Q1311K | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1179336049, COSV51645362; called by muse, mutect2, varscan2
- TUBB4A | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.176); catalogued as COSV51169650; called by muse, mutect2, varscan2
- ZGRF1 | c.4434C>A p.S1478R | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV71393913; called by muse, mutect2, varscan2
- CORIN | c.3055_3058del p.V1019Ifs*22 | Frame Shift Del (DEL) | VAF 31/130 reads (24%) | called by mutect2, pindel, varscan2
- NPSR1 | c.484C>A p.Q162K | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- EXOC1 | c.741A>G p.E247= | Silent (SNP) | VAF 29/112 reads (26%) | catalogued as COSV62122254; called by muse, mutect2, varscan2
- LLGL2 | c.513G>T p.S171= | Silent (SNP) | VAF 39/112 reads (35%) | catalogued as COSV51349058, COSV51418044; called by muse, varscan2
- TNRC6A | c.4314G>T p.P1438= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV59364615, COSV59370965; called by muse, mutect2, varscan2
